Somatic mutation profile of tumor specimen TCGA-EL-A3GX-01A (aliquot TCGA-EL-A3GX-01A-11D-A202-08) from TCGA case TCGA-EL-A3GX, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 41.6 years (15,212 days).
Specimen TCGA-EL-A3GX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7dde0da-9147-4ffd-a6dd-78f9b5212597.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3GX-10A (Blood Derived Normal), aliquot TCGA-EL-A3GX-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6cf89d49-b45e-479b-8fe6-34f81905c1c2

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ANKS1A | c.1514G>A p.G505D | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199969282, COSV64459589; called by muse, mutect2, varscan2
- MAP7D2 | c.2084C>T p.P695L | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as COSV65526356; called by muse, mutect2, varscan2
- PRB2 | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 124/568 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.148); catalogued as rs764959580, COSV66982670; called by muse, varscan2
- SLC39A14 | c.1169A>T p.N390I | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51483357; called by muse, mutect2, varscan2
- UBA6 | c.1861G>C p.E621Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); catalogued as COSV59175591; called by muse, mutect2, varscan2
- CEACAM5 | c.1776G>A p.G592= | Silent (SNP) | VAF 111/280 reads (40%) | catalogued as rs782624229, COSV55751417; called by muse, mutect2, varscan2
- PSMA4 | c.*1A>T | 3'UTR (SNP) | VAF 12/27 reads (44%) | catalogued as COSV99245659; called by muse, mutect2, varscan2
